Gene-level copy-number profile of tumor specimen TCGA-23-1111-01A from TCGA case TCGA-23-1111, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.4 years (23,171 days).
Specimen TCGA-23-1111-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.abe2d46a-0cd4-420d-9194-8e3588f3e696.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1111-10C (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1c91b529-0401-4444-9860-4dd41c63b2cc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 5,294; copy number 3: 12,267; copy number 4: 18,622; copy number 5: 15,014; copy number 6: 3,858; copy number 7: 3,499; copy number 8: 184; copy number 9: 661; copy number 11: 233; copy number 18: 132; copy number 62: 19; copy number 63: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-1111-01A-01D-0577-01): tumor purity 0.83, ploidy 4.22, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 937 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:53,985,845–54,034,888, 2 genes, copy number 62 (within-gene range 5–62): AC012531.3, HOXC6.
- chr12:53,994,895–54,189,008, 17 genes, copy number 62 (within-gene range 5–62): HOXC9, HOXC8, HOXC4, AC012531.2, AC012531.1, HOXC5, MIR615, FLJ12825, AC023794.3, AC023794.2, FAM242C, Y_RNA, SMUG1, LINC02381, AC023794.5, AC023794.4, AC023794.1.
- chr17:39,626,740–40,061,215, 24 genes, copy number 63 (within-gene range 3–63): PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124.
- chr19:10,111,693–17,848,071, 450 genes, copy number 9–11 (broad region; genes not listed).
- chr20:87,250–3,204,685, 105 genes, copy number 9 (broad region; genes not listed).
- chr20:23,350,791–23,674,888, 22 genes, copy number 9 (within-gene range 6–9): NXT1, LINC01431, GZF1, NAPB, RNA5SP479, CSTL1, CST11, AL096677.1, Y_RNA, CST12P, AL109954.1, AL109954.2, CST8, CST13P, CST9LP1, CST9L, CST9LP2, CST9, CST3, AL121894.2, AL121894.1, AL121894.3.
- chr20:31,377,164–33,650,036, 81 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr20:41,098,019–41,712,600, 17 genes, copy number 9: PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1, CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P, AL133229.1.
- chr20:43,667,019–45,348,424, 54 genes, copy number 9 (within-gene range 6–9): MYBL2, GTSF1L, RNU6-639P, LINC01728, TOX2, RN7SL443P, JPH2, AL035447.1, OSER1, OSER1-DT, GDAP1L1, FITM2, R3HDML, Y_RNA, AL117382.1, HNF4A, HNF4A-AS1, AL117382.2, MIR3646, LINC01620, RPL37AP1, TTPAL, SERINC3, PKIG, ADA, LINC01260, AL139352.1, KCNK15-AS1, CCN5, KCNK15, AL118522.1, RIMS4, PGBD4P2, AL008725.1, YWHAB, PABPC1L, TOMM34, STK4-AS1, STK4, Y_RNA, KCNS1, WFDC5, WFDC12, AL049767.1, PI3, SEMG1, SEMG2, AL035660.1, AL035660.2, SLPI, MATN4, RBPJL, SDC4, AL021578.1.
- chr20:45,881,227–52,890,386, 162 genes, copy number 9 (broad region; genes not listed).
- chr20:53,097,652–53,179,550, 3 genes, copy number 9: RN7SKP184, AL391097.3, AL391097.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
